Somatic mutation profile of tumor specimen TCGA-23-2645-01A (aliquot TCGA-23-2645-01A-01W-1091-09) from TCGA case TCGA-23-2645, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.1 years (19,758 days).
Specimen TCGA-23-2645-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06de60ac-cbed-4c42-b88c-6551daba8ed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2645-10A (Blood Derived Normal), aliquot TCGA-23-2645-10A-01W-1091-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/536272d0-9776-4a2b-adae-9752b4eec0bb

The open-access MAF lists 144 somatic variants for this specimen: 108 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 32, Splice Site 8, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 3, Splice Region 2, RNA 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY4 | c.2822C>G p.S941C | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100156927, COSV60253529; called by muse, mutect2, varscan2
- ANXA10 | c.530C>A p.A177E | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63738712; called by muse, mutect2, varscan2
- ARMC9 | c.348G>C p.P116= | Splice Region (SNP) | VAF 38/135 reads (28%) | catalogued as COSV100589708, COSV63020329; called by muse, mutect2, varscan2
- ARPC3 | c.116C>G p.T39R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.095); catalogued as rs758795905, COSV57399375; called by muse, mutect2, varscan2
- ASB16 | c.1148T>C p.V383A | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53234558; called by muse, mutect2, varscan2
- ATP11B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV60027719; called by muse, mutect2, varscan2
- BPTF | c.7696C>A p.Q2566K | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV58835290; called by muse, mutect2, varscan2
- CCDC103 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); catalogued as COSV53649996; called by muse, mutect2, varscan2
- CCDC88A | c.2390A>G p.Q797R | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as COSV55059940; called by muse, mutect2, varscan2
- CCT6B | c.1109G>C p.C370S | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58488642; called by muse, mutect2, varscan2
- CELF3 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1397063232, COSV51882855; called by muse, mutect2, varscan2
- CNN2 | c.630G>C p.M210I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV54027674; called by muse, mutect2, varscan2
- CYRIA | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 69/293 reads (24%) | catalogued as COSV62864765; called by muse, mutect2, varscan2
- CYTH4 | c.855C>G p.D285E | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV50631861; called by muse, mutect2, varscan2
- DCDC1 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV60839592, COSV60860485; called by muse, mutect2, varscan2
- DENND6A | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60768274; called by muse, mutect2, varscan2
- DHX37 | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV58133644; called by muse, mutect2, varscan2
- DRC1 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV56530483; called by muse, mutect2, varscan2
- DYSF | c.3843+1G>T p.X1281_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as CS053456, COSV50293849; called by muse, mutect2, varscan2
- ECI1 | c.199G>C p.V67L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs766980032, COSV100067107; called by muse, mutect2
- EMILIN1 | c.2050C>G p.R684G | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as COSV53154250; called by muse, mutect2, varscan2
- ERBB3 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs865824076, COSV57250810; called by muse, mutect2, varscan2
- ERGIC3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.584); catalogued as rs758603835, COSV54136988; called by muse, mutect2, varscan2
- FAM124A | c.542A>G p.D181G (on ENST00000322475 / NM_001242312.2; = p.D217G on NM_145019.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as rs961008632, COSV54475776; called by muse, mutect2, varscan2
- GC | c.916A>T p.M306L | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV56736773; called by muse, mutect2, varscan2
- GRINA | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV57592510; called by muse, mutect2, varscan2
- HNF4A | c.273C>A p.N91K | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV57381723; called by muse, mutect2, varscan2
- HPSE2 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 159/579 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1187622808, COSV65186575; called by muse, mutect2, varscan2
- HSD17B8 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100761773, COSV63002461; called by muse, mutect2, varscan2
- IL20RB | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV59047514; called by muse, mutect2, varscan2
- IQCK | c.182-1G>T p.X61_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV57522379; called by muse, mutect2, varscan2
- JAKMIP1 | c.1425G>C p.L475F | Missense Mutation (SNP) | VAF 120/517 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV51527672; called by muse, mutect2, varscan2
- KAT6A | c.3527G>C p.S1176T | Missense Mutation (SNP) | VAF 159/460 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55905122; called by muse, mutect2, varscan2
- KCNH7 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV59793486; called by muse, mutect2, varscan2
- KCNK10 | c.889A>C p.K297Q | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV56639861, COSV56642991; called by muse, mutect2, varscan2
- KRT6A | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV58106900; called by muse, mutect2, varscan2
- KRTAP13-1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 88/319 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100819824, COSV62663162; called by muse, mutect2, varscan2
- L3MBTL4 | c.1402A>T p.I468F | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.496); catalogued as COSV53119035; called by muse, mutect2, varscan2
- MARCHF10 | c.509C>A p.A170E | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as COSV60886475; called by muse, mutect2, varscan2
- MBD5 | c.1145A>C p.H382P | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV68696524; called by muse, mutect2, varscan2
- MCAM | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50633914; called by muse, mutect2, varscan2
- MCTP2 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV59142913; called by muse, mutect2, varscan2
- MED13L | c.4936T>C p.S1646P | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56118457; called by muse, mutect2, varscan2
- MFSD6 | c.1793-1G>A p.X598_splice | Splice Site (SNP) | VAF 54/264 reads (20%) | catalogued as rs753868608, COSV99855476; called by muse, mutect2
- MFSD6L | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.454); catalogued as rs1276956604, COSV61002540; called by muse, mutect2, varscan2
- MINDY3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 173/207 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs746264268, COSV53219675; called by muse, mutect2, varscan2
- MRGPRF | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs1227879038, COSV57995725; called by muse, mutect2, varscan2
- MYLK3 | c.302A>C p.Q101P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV67363661; called by muse, mutect2, varscan2
- NCAN | c.3549C>A p.D1183E | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53049726; called by muse, mutect2, varscan2
- NFATC2 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV65354900; called by muse, mutect2, varscan2
- NLRP7 | c.2894G>C p.C965S (on ENST00000340844 / NM_206828.3; = p.C994S on NM_139176.3) | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV104406878, COSV60173016; called by muse, mutect2, varscan2
- NRAS | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as rs1385254281, COSV54743878; called by muse, mutect2, varscan2
- NRG3 | c.1576T>G p.C526G | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV64555713; called by muse, mutect2, varscan2
- NUP155 | c.2778T>G p.Y926* (on ENST00000231498 / NM_153485.3; = p.Y867* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 38/185 reads (21%) | catalogued as COSV51528970; called by muse, mutect2, varscan2
- ODF2 | c.874G>T p.A292S (on ENST00000434106 / NM_153433.2; = p.A268S on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as COSV63546525; called by muse, mutect2, varscan2
- OSBPL10 | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV101160047; called by muse, mutect2
- OTOF | c.963G>T p.V321= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV55500740; called by muse, mutect2, varscan2
- PAK1IP1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV65435406; called by muse, mutect2, varscan2
- PCDHB3 | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV50568976; called by muse, mutect2, varscan2
- PCDHB6 | c.490A>C p.N164H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99173579; called by muse, mutect2, varscan2
- PDGFRB | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1176688330, COSV55803556; called by muse, varscan2
- PLAA | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV68304746; called by muse, mutect2, varscan2
- PNISR | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65079235; called by muse, mutect2, varscan2
- RBM15B | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as COSV60042162; called by muse, mutect2, varscan2
- RORC | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1209731485, COSV59091868; called by muse, mutect2, varscan2
- SAMD4B | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 146/591 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.986); catalogued as COSV55393385; called by muse, mutect2, varscan2
- SCAF4 | c.2688del p.F897Lfs*9 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | catalogued as rs1568817194, COSV54255532; called by mutect2, pindel, varscan2
- SEC23B | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV99358222; called by muse, mutect2
- SLA | c.251G>A p.W84* (on ENST00000338087 / NM_001045556.3; = p.W124* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 27/214 reads (13%) | catalogued as rs937244481, COSV55072396; called by muse, mutect2, varscan2
- SLC38A11 | c.996A>T p.E332D (on ENST00000409149 / NM_001351539.1; = p.E310D on NM_173512.2) | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.101); catalogued as COSV58053135; called by muse, mutect2, varscan2
- SLC38A2 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338317225, COSV56744684; called by muse, varscan2
- SLC41A3 | c.1366+2T>C p.X456_splice (on ENST00000315891 / NM_001008485.2; = p.G456= on NM_017836.4) | Splice Site (SNP) | VAF 54/354 reads (15%) | catalogued as COSV59987758; called by muse, mutect2, varscan2
- SLITRK1 | c.418A>G p.N140D | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65675092; called by muse, mutect2, varscan2
- SLK | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59824854; called by muse, mutect2, varscan2
- SMC6 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1360857081, COSV61173389; called by muse, mutect2, varscan2
- SMCP | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 188/729 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs61814549, COSV100908379; called by muse, mutect2, varscan2
- SNX25 | c.2133G>T p.Q711H | Missense Mutation (SNP) | VAF 150/484 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53013317; called by muse, mutect2, varscan2
- SORCS1 | c.2261C>G p.S754* | Nonsense Mutation (SNP) | VAF 41/232 reads (18%) | catalogued as COSV53857179; called by muse, mutect2, varscan2
- TBX22 | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV64785581; called by muse, mutect2, varscan2
- TCF20 | c.3986C>G p.P1329R | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs776058464; called by muse, mutect2
- TMEM200A | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 139/471 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV51651727; called by muse, mutect2, varscan2
- TP53 | c.420del p.C141Afs*29 | Frame Shift Del (DEL) | VAF 72/137 reads (53%) | catalogued as COSV52700425; called by mutect2, pindel, varscan2
- TPBG | c.1250A>C p.N417T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV63882484; called by muse, mutect2, varscan2
- UBR2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs923068120, COSV65768232, COSV65769861; called by muse, mutect2, varscan2
- UTP11 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV65951266; called by muse, mutect2, varscan2
- VCL | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.24); catalogued as rs758811315, COSV53008382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VIP | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100923977; called by muse, mutect2
- VWA2 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV53905987; called by muse, mutect2, varscan2
- WBP1L | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64009569, COSV64009581; called by muse, mutect2, varscan2
- WDR11 | c.3203A>G p.Q1068R | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54787374; called by muse, mutect2, varscan2
- WDR6 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58244656; called by muse, mutect2, varscan2
- ZC3H3 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52789104; called by muse, mutect2, varscan2
- ZDHHC15 | c.916C>G p.P306A | Missense Mutation (SNP) | VAF 141/253 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV64901338; called by muse, mutect2, varscan2
- ZMYM6 | c.731G>T p.S244I | Missense Mutation (SNP) | VAF 106/148 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV58184095; called by muse, mutect2, varscan2
- ZNF44 | c.602G>A p.R201H (on ENST00000356109 / NM_001164276.2; = p.R153H on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs372299239; called by muse, mutect2, varscan2
- ZNF665 | c.1444T>C p.C482R (on ENST00000600412; = p.C547R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67214474; called by muse, mutect2, varscan2
- C2orf15 | c.-97_-77+22del | Splice Site (DEL) | VAF 22/247 reads (9%) | called by mutect2, pindel
- COL17A1 | c.306_314del p.H103_T105del | In Frame Del (DEL) | VAF 36/246 reads (15%) | called by mutect2, pindel, varscan2
- DCLRE1A | c.752_764del p.H251Pfs*16 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- DCUN1D1 | c.222_246del p.D74Efs*2 | Frame Shift Del (DEL) | VAF 68/340 reads (20%) | called by mutect2, pindel
- IGFBP1 | c.654_661del p.E218Dfs*36 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | called by mutect2, pindel, varscan2
- KIF20A | c.2126-13_2137del p.X709_splice | Splice Site (DEL) | VAF 20/188 reads (11%) | called by mutect2, pindel
- LENG8 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- MYBPC1 | c.356_363+7del p.X119_splice (on ENST00000550270 / NM_206820.2; = p.X144_splice on NM_002465.4) | Splice Site (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- OTOF | c.308_316del p.D103_N105del | In Frame Del (DEL) | VAF 46/253 reads (18%) | called by mutect2, pindel, varscan2
- PKHD1 | c.11946_11979del p.A3983Kfs*44 | Frame Shift Del (DEL) | VAF 53/320 reads (17%) | called by mutect2, pindel
- PLD1 | c.1950_1970del p.C650_D656del | In Frame Del (DEL) | VAF 92/606 reads (15%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.2623-5_2623del p.X875_splice | Splice Site (DEL) | VAF 72/456 reads (16%) | called by mutect2, pindel, varscan2
- AACS | c.1734C>T p.Y578= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV55535887; called by muse, mutect2, varscan2
- AKAP12 | c.5016A>G p.T1672= | Silent (SNP) | VAF 111/301 reads (37%) | catalogued as COSV53573233; called by muse, mutect2, varscan2
- BCO2 | c.1578T>C p.N526= | Silent (SNP) | VAF 76/381 reads (20%) | catalogued as rs1566804505, COSV63063042; called by muse, mutect2, varscan2
- CHD6 | c.3228C>T p.D1076= | Silent (SNP) | VAF 100/438 reads (23%) | catalogued as rs182170504, COSV58555997; called by mutect2, varscan2
- DIP2B | c.2061A>T p.P687= | Silent (SNP) | VAF 94/393 reads (24%) | catalogued as COSV56581941; called by muse, mutect2, varscan2
- DYNC1H1 | c.981A>G p.E327= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV64136068; called by muse, mutect2, varscan2
- ENPP1 | c.2760C>T p.T920= | Silent (SNP) | VAF 166/224 reads (74%) | catalogued as COSV62931651; called by muse, varscan2
- FRG1 | c.444T>A p.A148= | Silent (SNP) | VAF 80/175 reads (46%) | catalogued as COSV56999246; called by muse, mutect2, varscan2
- GSTM4 | c.543G>A p.L181= | Silent (SNP) | VAF 102/335 reads (30%) | catalogued as COSV58694363; called by muse, mutect2, varscan2
- IRS1 | c.2890A>C p.R964= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV59335354; called by muse, mutect2, varscan2
- LIG1 | c.1482G>A p.T494= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs753665588, COSV54390816; called by muse, mutect2, varscan2
- MAP1B | c.1752A>G p.E584= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV57097405; called by muse, mutect2, varscan2
- MEGF10 | c.1857T>C p.F619= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57247927; called by muse, mutect2, varscan2
- MIPEP | c.933T>C p.A311= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV66300253; called by muse, mutect2, varscan2
- MYLK | c.1692C>T p.G564= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1443517334, COSV60608444; called by muse, mutect2, varscan2
- NELFE | c.396G>C p.L132= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV64811104; called by muse, mutect2, varscan2
- NPSR1 | c.642G>C p.V214= | Silent (SNP) | VAF 79/425 reads (19%) | catalogued as COSV62199213, COSV62208797; called by muse, mutect2, varscan2
- OGDHL | c.1758C>G p.P586= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV65101895, COSV65103577; called by muse, mutect2, varscan2
- OR14I1 | c.759G>T p.G253= | Silent (SNP) | VAF 58/96 reads (60%) | catalogued as COSV61199427; called by muse, mutect2, varscan2
- PCDHB14 | c.402A>C p.L134= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV53387847; called by muse, mutect2, varscan2
- PRAME | c.1050G>A p.Q350= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV101287019, COSV67161353; called by muse, mutect2, varscan2
- PRMT2 | c.801C>T p.N267= | Silent (SNP) | VAF 59/113 reads (52%) | catalogued as rs781148398, COSV52454957; called by muse, mutect2, varscan2
- ROS1 | c.1533C>T p.V511= | Silent (SNP) | VAF 95/292 reads (33%) | catalogued as rs760417047, COSV63853808; called by muse, mutect2, varscan2
- SLC6A18 | c.1780C>A p.R594= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1399461138, COSV99722752, COSV99722760; called by muse, mutect2
- SOAT2 | c.1248C>T p.A416= | Silent (SNP) | VAF 77/444 reads (17%) | catalogued as rs773521555; called by muse, mutect2
- STAB2 | c.1986C>G p.P662= | Silent (SNP) | VAF 176/466 reads (38%) | catalogued as COSV66337631; called by muse, mutect2, varscan2
- TRIM15 | c.141G>T p.G47= | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV64989257; called by muse, mutect2, varscan2
- VASH1 | c.450G>C p.L150= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV51335709; called by muse, mutect2, varscan2
- VENTX | c.372G>A p.L124= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58084373; called by muse, mutect2, varscan2
- VPS52 | c.660C>T p.C220= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs767483221, COSV71403454; called by muse, mutect2, varscan2
- WDR47 | c.1281A>G p.Q427= (on ENST00000369962 / NM_001142551.2; = p.Q428= on NM_014969.5) | Silent (SNP) | VAF 77/260 reads (30%) | catalogued as rs775158339, COSV100728503; called by muse, mutect2, varscan2
- XIRP1 | c.5514C>T p.S1838= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV61137926; called by muse, mutect2, varscan2
- ATG2A | chr11:64891143 A>C | 3'Flank (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MYOT | c.-13_2del | 5'UTR (DEL) | VAF 78/218 reads (36%) | called by mutect2, pindel, varscan2
- TUBB7P | n.654C>A | RNA (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- ZNF767P | n.548C>G | RNA (SNP) | VAF 918/1100 reads (83%) | called by muse, mutect2, varscan2
